Gene-level copy-number profile of tumor specimen TCGA-10-0928-01A from TCGA case TCGA-10-0928, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 71.4 years (26,066 days).
Specimen TCGA-10-0928-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.53d6550d-4d80-4e28-accb-fd3a46abcdd5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-10-0928-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e253de3e-108a-4bc6-a0ca-155c0587abd3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 72; copy number 1: 23,767; copy number 2: 29,167; copy number 3: 5,740; copy number 4: 813; copy number 5: 217; copy number 6: 31.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-10-0928-01A-02D-0399-01): tumor purity 0.95, ploidy 1.74, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 72 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:31,522,480–31,803,980, 4 genes: SRD5A2, AL133247.1, AL133247.2, LINC01946.
- chr4:97,916,353–97,917,401, 1 gene: CRYZP2.
- chr8:4,317,388–4,635,654, 3 genes: AC027251.1, AC010941.1, AC022068.1.
- chr9:3,824,127–4,348,392, 1 gene (within-gene range 0–1): GLIS3.
- chr9:4,070,906–4,679,502, 8 genes: AL359095.1, AL162419.1, RNU6-694P, SLC1A1, SPATA6L, AL136231.1, PLPP6, CDC37L1-DT.
- chr11:48,216,810–49,208,638, 42 genes: OR4B1, OR4B2P, OR4X2, OR4X1, OR4S1, OR4C3, OR4C4P, OR4C5, OR4C2P, OR4C10P, OR4C9P, OR4R1P, OR4A47, OR4A48P, OR4A46P, OR4A40P, OR4A43P, OR4A45P, OR4A41P, OR4A42P, OR4A44P, AC027369.6, AC027369.3, AC027369.4, AC027369.5, TRIM51CP, AC027369.2, TRIM51GP, TRIM53CP, AC027369.1, TRIM49B, AC084851.4, TRIM64C, AC084851.3, AC084851.1, UBTFL7, AC084851.2, AC118273.1, AC118273.2, TRIM77BP, UBTFL9, FOLH1.
- chr11:50,018,798–50,361,706, 13 genes: OR4C48P, OR4C45, OR4C49P, GTF2IP11, AC109635.3, AC109635.6, AC109635.5, PHKG1P3, AC109635.4, AC109635.2, AC109635.1, LINC02750, AC024405.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 248 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:13,437,942–13,982,002, 1 gene, copy number 5 (within-gene range 3–5): GRIN2B.
- chr12:13,526,854–28,581,511, 237 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr12:28,821,975–29,381,189, 10 genes, copy number 5: AC022081.1, AC024255.1, AC012150.1, FAR2, AC012150.2, AC009318.4, AC009318.1, AC009318.3, AC009318.2, ERGIC2.

Autosomal genes at a single copy (total copy number 1): 22,836. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
